Gene-level copy-number profile of tumor specimen TCGA-B5-A1MY-01A from TCGA case TCGA-B5-A1MY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-B5-A1MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.2ea42ae0-4d58-4dfc-bf31-b78c3f40e92e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A1MY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b77d5323-7539-4474-ba27-3a9e32b5ac54

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,249; copy number 2: 18,707; copy number 3: 23,106; copy number 4: 9,773; copy number 5: 4,083; copy number 6: 1,518; copy number 7: 624; copy number 8: 48; copy number 9: 109; copy number 10: 67; copy number 11: 205; copy number 15: 46; copy number 21: 103; copy number 24: 79; copy number 35: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A1MY-01A-11D-A141-01): tumor purity 0.71, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,367 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:13,460,294–13,506,424, 4 genes, copy number 8: AC027124.2, AC027124.1, HDAC11-AS1, HDAC11.
- chr3:101,163,094–101,320,575, 2 genes, copy number 7: ACTR3P3, IMPG2.
- chr3:101,357,292–101,359,242, 1 gene, copy number 7: ZNF90P1.
- chr5:58,198–18,049,872, 342 genes, copy number 7 (broad region; genes not listed).
- chr5:137,867,858–138,338,355, 16 genes, copy number 10 (within-gene range 5–10): MYOT, PKD2L2, FAM13B, AC113382.1, AC113382.2, RNU6-1148P, WNT8A, NME5, RNU6-460P, RNU6-888P, BRD8, KIF20A, CDC23, GFRA3, RPS27AP18, CDC25C.
- chr7:7,356,203–9,189,857, 26 genes, copy number 7: COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3.
- chr7:67,278,714–69,597,493, 28 genes, copy number 8–11: SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr8:40,900,016–42,371,808, 37 genes, copy number 8–11: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23.
- chr12:24,704,503–24,775,565, 1 gene, copy number 10 (within-gene range 6–10): AC023796.1.
- chr12:24,810,024–25,195,162, 11 genes, copy number 10 (within-gene range 6–10): BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94.
- chr15:90,811,528–90,935,196, 8 genes, copy number 10: AC124248.2, AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3.
- chr16:11,976,734–12,574,287, 1 gene, copy number 9 (within-gene range 6–9): SNX29.
- chr16:12,086,746–14,953,120, 63 genes, copy number 9 (broad region; genes not listed).
- chr16:14,988,259–15,056,079, 4 genes, copy number 9 (within-gene range 4–9): AC138932.2, MIR1972-1, AC138932.4, NTAN1.
- chr17:31,759,795–32,446,038, 39 genes, copy number 7: GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2.
- chr17:39,404,285–41,492,546, 135 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:80,134,369–81,707,517, 79 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:9,324,174–10,598,965, 77 genes, copy number 9–15 (within-gene range 2–15) (broad region; genes not listed).
- chr19:28,869,507–40,629,818, 462 genes, copy number 11–35 (within-gene range 2–35) (broad region; genes not listed).
- chr20:4,059,633–4,685,148, 9 genes, copy number 7 (within-gene range 4–7): RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2.
- chr20:44,531,785–45,176,544, 22 genes, copy number 7 (within-gene range 4–7): PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, AL049767.1, PI3.

Autosomal genes at a single copy (total copy number 1): 871. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
